Somatic mutation profile of tumor specimen HCM-CSHL-0160-C18-01B (aliquot HCM-CSHL-0160-C18-01B-01D-A78L-36) from HCMI case HCM-CSHL-0160-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 83.9 years (30,635 days).
Specimen HCM-CSHL-0160-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 151fcc5f-5c5b-4b61-a409-e7a1777b210c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0160-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0160-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13522a63-ca7f-44e0-9b58-1fd3f08e1e48

The open-access MAF lists 113 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Intron 10, Nonsense Mutation 4, Frame Shift Del 4, 5'Flank 3, Frame Shift Ins 3, RNA 3, 3'Flank 2, Splice Site 2, In Frame Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 56/208 reads (27%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 59/348 reads (17%) | catalogued as CS971608, COSV57347627, COSV99970657; called by muse, mutect2, varscan2
- C8A | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs145559867; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CCDC102A | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477882903; called by muse, mutect2
- CHD4 | c.4464G>C p.L1488F (on ENST00000357008 / NM_001363606.2; = p.L1501F on NM_001273.5) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100537997, COSV58901234; called by muse, mutect2
- CHD4 | c.1582C>T p.R528W (on ENST00000357008 / NM_001363606.2; = p.R541W on NM_001273.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58899913; called by muse, mutect2, varscan2
- CNOT9 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99813791; called by muse, varscan2
- CNTN4 | c.1979C>G p.T660S | Missense Mutation (SNP) | VAF 118/586 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100639251; called by muse, mutect2, varscan2
- CRB1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 151/640 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); catalogued as rs1355316419, COSV66334620; called by muse, mutect2, varscan2
- DCLK1 | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV99713821; called by muse, mutect2, varscan2
- DDR2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376303676; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs754135731; called by mutect2, varscan2*
- ENPP1 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs762065573, COSV62933486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXL1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV100206189; called by muse, mutect2, varscan2
- GLB1L | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs142820300; called by muse, mutect2, varscan2
- GPT | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as rs370395815; called by muse, mutect2, varscan2
- HK3 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs372314303; called by muse, mutect2, varscan2
- IQCF5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1300020072; called by muse, mutect2, varscan2
- IRX5 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.224); catalogued as rs1235972509, COSV58058600; called by muse, varscan2
- KCTD15 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs762950630; called by muse, mutect2, varscan2
- MAGEB6B | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs777950806, COSV69689790; called by muse, mutect2, varscan2
- MROH8 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 329/634 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as rs781139699; called by muse, mutect2, varscan2
- NBEA | c.2931G>T p.K977N | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1344551973; called by muse, mutect2, varscan2
- PCDH17 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961753265; called by muse, mutect2, varscan2
- PDE1B | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1318082863, COSV54491363; called by muse, mutect2, varscan2
- PDZD2 | c.7216G>A p.E2406K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs374749952; called by muse, mutect2, varscan2
- RBM20 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs919432113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF17 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759166286, COSV55039640, COSV55041052; called by muse, mutect2
- SIPA1 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63134853; called by muse, mutect2
- SKIDA1 | c.693_698del p.A243_A244del | In Frame Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs754621872; called by mutect2, varscan2
- SLC25A26 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 67/393 reads (17%) | catalogued as rs755461919; called by muse, mutect2, varscan2
- SLC6A11 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99039147; called by muse, mutect2, varscan2
- SMARCC2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57213988; called by muse, mutect2, varscan2
- ST8SIA5 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 52/252 reads (21%) | PolyPhen possibly damaging (0.738); catalogued as rs779525312, COSV100164483; called by muse, mutect2, varscan2
- SYNGAP1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 83/485 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1561781934, COSV53386049; called by muse, mutect2, varscan2
- TENM1 | c.7382G>A p.R2461Q | Missense Mutation (SNP) | VAF 55/542 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs752625441; called by muse, mutect2, varscan2
- TESPA1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs375755904; called by muse, mutect2, varscan2
- THEMIS | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64072833; called by muse, mutect2, varscan2
- TNC | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs763289734, COSV60785514; called by muse, mutect2, varscan2
- TRIM48 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 67/433 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs747964790; called by muse, mutect2, varscan2
- UTRN | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs143774718; called by muse, mutect2, varscan2
- VWA7 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as rs1442938143; called by muse, mutect2, varscan2
- APC | c.2490_2491dup p.L831Cfs*12 | Frame Shift Ins (INS) | VAF 72/345 reads (21%) | called by mutect2, pindel, varscan2
- CCNI | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CHD4 | c.4891G>C p.E1631Q (on ENST00000357008 / NM_001363606.2; = p.E1642Q on NM_001273.5) | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, varscan2
- CMTR2 | c.1611T>G p.F537L | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF17 | c.989dup p.N330Kfs*14 | Frame Shift Ins (INS) | VAF 52/370 reads (14%) | called by mutect2, pindel, varscan2
- EFR3A | c.2087G>T p.R696I | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- EMSY | c.2477del p.V826Gfs*2 | Frame Shift Del (DEL) | VAF 28/216 reads (13%) | called by mutect2, pindel, varscan2
- GATAD2B | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HPS3 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF18A | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDB3 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MBNL2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NAA15 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- OR56A3 | c.122T>A p.L41* | Nonsense Mutation (SNP) | VAF 61/276 reads (22%) | called by muse, mutect2, varscan2
- OR5M8 | c.865del p.Y289Ifs*8 | Frame Shift Del (DEL) | VAF 64/283 reads (23%) | called by mutect2, pindel, varscan2
- PDE10A | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.12257del p.L4086Rfs*112 (on ENST00000262304 / NM_001009944.3; = p.L4085Rfs*112 on NM_000296.4) | Frame Shift Del (DEL) | VAF 26/157 reads (17%) | called by mutect2, pindel, varscan2
- PTPRM | c.861del p.P288Lfs*6 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- RAMP3 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFTN2 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SMC4 | c.1824dup p.S609Ifs*18 | Frame Shift Ins (INS) | VAF 36/240 reads (15%) | called by mutect2, varscan2
- SUFU | c.456_457del p.X152_splice | Splice Site (DEL) | VAF 50/268 reads (19%) | called by pindel, varscan2
- SYT1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- TLK2 | c.1787G>T p.G596V (on ENST00000326270 / NM_001284333.2; = p.G574V on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM200A | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM24 | c.751C>A p.H251N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM43B | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- USP37 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZPLD1 | c.688G>A p.V230I (on ENST00000466937 / NM_001329788.1; = p.V246I on NM_175056.2) | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- B3GNT6 | c.801G>A p.P267= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- C11orf87 | c.444G>A p.S148= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs779890093, COSV100535703; called by muse, mutect2, varscan2
- C1QL2 | c.123C>T p.G41= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- DHX16 | c.744G>A p.A248= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as rs559637615; called by muse, mutect2, varscan2
- EIPR1 | c.870G>A p.T290= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as rs761019969, COSV66132065, COSV66133651; called by muse, mutect2, varscan2
- EPHA3 | c.1200G>A p.L400= | Silent (SNP) | VAF 65/320 reads (20%) | called by muse, mutect2, varscan2
- FANCB | c.2394C>T p.V798= | Silent (SNP) | VAF 41/297 reads (14%) | catalogued as rs190579053, COSV100146578; ClinVar: benign; called by muse, mutect2, varscan2
- FLT4 | c.2127C>T p.I709= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV56097933; called by muse, mutect2, varscan2
- LCORL | c.357T>C p.S119= | Silent (SNP) | VAF 54/331 reads (16%) | called by muse, mutect2, varscan2
- LSS | c.1485T>C p.N495= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as rs985166790; called by muse, mutect2, varscan2
- MMP2 | c.681C>T p.N227= | Silent (SNP) | VAF 78/392 reads (20%) | catalogued as rs558609366, COSV54604672; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4D10 | c.834C>A p.I278= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- PGP | c.183G>A p.K61= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs1263222794; called by muse, mutect2, varscan2
- TBCD | c.1554G>C p.V518= | Silent (SNP) | VAF 42/197 reads (21%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1032C>T p.S344= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TRBV23-1 | c.6C>A p.G2= | Silent (SNP) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- TRIM51 | c.177G>A p.T59= | Silent (SNP) | VAF 36/167 reads (22%) | catalogued as rs747498461, COSV55268028; called by muse, mutect2, varscan2
- USP28 | c.2946G>A p.L982= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- USP29 | c.2496C>A p.I832= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV54145949; called by muse, mutect2, varscan2
- WIZ | c.1041G>A p.A347= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs927604183; called by muse, mutect2, varscan2
- AC245047.1 | n.107C>T | RNA (SNP) | VAF 21/233 reads (9%) | called by muse, mutect2
- ACBD5 | chr10:27196357 G>A | 3'Flank (SNP) | VAF 144/823 reads (17%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100105888 C>T | 5'Flank (SNP) | VAF 67/347 reads (19%) | catalogued as rs1200636499; called by muse, mutect2, varscan2
- AL110118.1 | c.207+2478G>A | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840559 G>T | 5'Flank (SNP) | VAF 36/61 reads (59%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849031 A>G | 5'Flank (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- ASL | c.602+38G>A | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- ATP6AP2 | c.-7C>T | 5'UTR (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- CAMK2G | c.1273+725C>T | Intron (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1479G>C | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as rs971864132; called by muse, varscan2
- FKBP11 | c.388+207G>A | Intron (SNP) | VAF 64/304 reads (21%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-968A>T | Intron (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- IDS | c.419-1082C>T | Intron (SNP) | VAF 23/193 reads (12%) | catalogued as rs782598072; called by muse, mutect2, varscan2
- MAP4K4 | chr2:101893239 G>T | 3'Flank (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85441C>T | Intron (SNP) | VAF 98/456 reads (21%) | catalogued as rs537870223, COSV72275109; called by muse, varscan2
- MUC19 | n.5591G>T | RNA (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- NPIPP1 | n.262C>T | RNA (SNP) | VAF 78/626 reads (12%) | called by muse, mutect2, varscan2
- PPAT | c.403-659A>C | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- SDHA | c.1794+98C>T | Intron (SNP) | VAF 67/351 reads (19%) | called by muse, varscan2
- ZNF747 | c.*520G>T | 3'UTR (SNP) | VAF 39/233 reads (17%) | catalogued as rs1239556758; called by muse, mutect2, varscan2
